EXCEPTIONAL_RESPONDERS case ER-B1PU — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e59e0c93-d1c5-4853-bc9e-c560d46ab0f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 48.6 years (17,761 days); Year of diagnosis: 2006; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 4,201 days (11.5 years); Days to best overall response: 41 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 41 days; Days to treatment end: 3,928 days (10.8 years).

Follow-up (1 entry)
- Days to follow up: 4,201 days (11.5 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 4,201 days (11.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B1PU-TTP1-A: Sample type: Slides; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1PU-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 2; Percent tumor nuclei: 3; Percent normal cells: 70; Percent necrosis: 3; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
